Somatic mutation profile of cancer-model specimen HCM-CSHL-0379-C18-85A (3D Organoid; aliquot HCM-CSHL-0379-C18-85A-01D-A79C-36), derived from the primary tumor of HCMI case HCM-CSHL-0379-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 72.3 years (26,410 days).
Specimen HCM-CSHL-0379-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ddcf4235-be16-4a41-9d16-8c53b54cbf54.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0379-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0379-C18-10A-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8dacbdfa-ccad-4e69-bb05-5c3e62abeeee

The open-access MAF lists 114 somatic variants for this specimen: 93 protein-altering or splice-affecting, 17 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 82, Silent 17, Nonsense Mutation 8, Intron 2, Frame Shift Del 2, 5'UTR 1, In Frame Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 53/123 reads (43%) | hotspot (GDC flag); catalogued as rs587781392, CM920027, COSV57321978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 145/283 reads (51%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.2329G>T p.V777L | Missense Mutation (SNP) | VAF 2267/2427 reads (93%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as rs121913471, COSV54062385, COSV54062767, COSV54069186; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RALA | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 119/385 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1554297905, COSV50049211; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS2 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 169/330 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs752634323, COSV51072804, COSV51081870; called by muse, mutect2, varscan2
- ANKRD30A | c.1133del p.G378Efs*19 (on ENST00000611781; = p.G322Efs*19 on NM_052997.2) | Frame Shift Del (DEL) | VAF 180/432 reads (42%) | catalogued as COSV64624129; called by mutect2, pindel, varscan2
- APBA2 | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 197/390 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376193947; called by muse, mutect2, varscan2
- BOC | c.2981C>T p.P994L | Missense Mutation (SNP) | VAF 104/264 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.078); catalogued as rs1029862359, COSV56355168; called by muse, mutect2, varscan2
- CAPN9 | c.320C>T p.T107M | Missense Mutation (SNP) | VAF 141/306 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs370370799; called by muse, mutect2, varscan2
- CCDC87 | c.1181G>T p.R394L | Missense Mutation (SNP) | VAF 217/339 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as rs199906600, COSV59578459; called by muse, mutect2, varscan2
- CLCNKB | c.1477G>A p.G493S | Missense Mutation (SNP) | VAF 238/464 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777095700; called by muse, mutect2, varscan2
- CREB5 | c.179C>T p.P60L (on ENST00000357727 / NM_182898.4; = p.P53L on NM_004904.3) | Missense Mutation (SNP) | VAF 78/269 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760077074, COSV63220219; called by muse, mutect2, varscan2
- DISP3 | c.592A>G p.N198D | Missense Mutation (SNP) | VAF 209/481 reads (43%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs769299495; called by muse, mutect2, varscan2
- DNM3 | c.2327C>T p.T776I (on ENST00000355305 / NM_001350206.2; = p.T770I on NM_015569.5) | Missense Mutation (SNP) | VAF 31/461 reads (7%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.01); catalogued as rs1326122034; called by muse, mutect2
- ELFN2 | c.1952C>T p.P651L | Missense Mutation (SNP) | VAF 241/483 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.111); catalogued as rs372217764; called by muse, mutect2, varscan2
- FBXW10 | c.1729G>A p.V577M | Missense Mutation (SNP) | VAF 122/122 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759260883; called by muse, varscan2
- GPR137B | c.1017C>A p.F339L | Missense Mutation (SNP) | VAF 109/266 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs373821559, COSV63992300, COSV63992625; called by muse, mutect2, varscan2
- GPR173 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 391/391 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100212124; called by muse, mutect2, varscan2
- HECW1 | c.1669C>T p.R557W | Missense Mutation (SNP) | VAF 203/639 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs764159115, COSV67835274; called by muse, mutect2, varscan2
- HYDIN | c.7829C>T p.P2610L | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs1371650515; called by muse, mutect2, varscan2
- JUP | c.1744C>T p.R582W | Missense Mutation (SNP) | VAF 10/297 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as rs782205755; called by muse, mutect2
- KCNB2 | c.272G>C p.R91P | Missense Mutation (SNP) | VAF 173/347 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73050758; called by muse, mutect2, varscan2
- KCNQ3 | c.2381C>T p.S794L | Missense Mutation (SNP) | VAF 182/349 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs267601778; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIFAP3 | c.1949G>A p.R650Q | Missense Mutation (SNP) | VAF 64/155 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs373189946, COSV100846894; called by muse, mutect2, varscan2
- LAMC1 | c.3595C>T p.R1199* | Nonsense Mutation (SNP) | VAF 123/224 reads (55%) | catalogued as COSV51154755, COSV99280014; called by muse, mutect2, varscan2
- MEGF6 | c.4364G>A p.R1455H | Missense Mutation (SNP) | VAF 146/316 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.899); catalogued as rs778623137; called by muse, mutect2, varscan2
- MICB | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 259/612 reads (42%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.994); catalogued as rs766185724, COSV52855463; called by muse, mutect2, varscan2
- MXRA5 | c.8095C>T p.R2699C | Missense Mutation (SNP) | VAF 396/400 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54252600; called by muse, mutect2
- NEURL2 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 66/838 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV51944619; called by muse, mutect2
- NRG3 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 14/422 reads (3%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV64573833; called by muse, mutect2
- OR51F1 | c.443C>A p.S148Y | Missense Mutation (SNP) | VAF 34/250 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV100598868, COSV58579217; called by muse, mutect2, varscan2
- OVOL2 | c.335C>T p.T112M | Missense Mutation (SNP) | VAF 95/327 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.569); catalogued as rs762166610; called by muse, mutect2, varscan2
- PCDHA11 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 32/536 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV56519324; called by muse, mutect2
- PCDHB3 | c.2156C>T p.A719V | Missense Mutation (SNP) | VAF 283/576 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.847); catalogued as rs1554272676; called by muse, mutect2, varscan2
- PCDHGA10 | c.2119G>A p.V707I | Missense Mutation (SNP) | VAF 284/560 reads (51%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.017); catalogued as rs369551410; called by muse, varscan2
- PTPRF | c.4234G>T p.D1412Y | Missense Mutation (SNP) | VAF 132/267 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100740851, COSV100741255; called by muse, mutect2
- PTPRS | c.4661C>T p.A1554V | Missense Mutation (SNP) | VAF 176/350 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1191088838, COSV53620761; called by muse, mutect2, varscan2
- PXDN | c.3319C>T p.R1107W | Missense Mutation (SNP) | VAF 30/514 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs900790636, COSV53247325; called by muse, mutect2
- PXDNL | c.2959G>A p.A987T | Missense Mutation (SNP) | VAF 163/482 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.037); catalogued as rs768124415, COSV62479981, COSV62493818; called by muse, mutect2, varscan2
- RNGTT | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 109/223 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0.115); catalogued as COSV55647670; called by muse, mutect2, varscan2
- RYR1 | c.4821G>A p.M1607I | Missense Mutation (SNP) | VAF 75/491 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); catalogued as rs771870872; called by muse, mutect2, varscan2
- SLITRK1 | c.870C>A p.F290L | Missense Mutation (SNP) | VAF 152/477 reads (32%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV65674904; called by muse, mutect2, varscan2
- SPATA31A3 | c.1786C>T p.R596W | Missense Mutation (SNP) | VAF 119/261 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1426644880; called by muse, mutect2, varscan2
- TCFL5 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 320/491 reads (65%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.566); catalogued as rs780872850, COSV53896319; called by muse, mutect2, varscan2
- TEKT4 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 180/374 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs114824441, COSV54622572; called by muse, mutect2, varscan2
- TEX15 | c.1504G>T p.D502Y (on ENST00000256246; = p.D885Y on NM_001350162.2) | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV56346990; called by muse, mutect2, varscan2
- THBD | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 146/758 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs1186245570; called by muse, mutect2, varscan2
- TMEM200A | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 138/293 reads (47%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs201700503, COSV51648975, COSV99759901; called by muse, mutect2, varscan2
- TMEM71 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 92/216 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs200344505, COSV100785636, COSV63457874; called by muse, mutect2, varscan2
- TPST1 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 290/428 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs376840313; called by muse, mutect2, varscan2
- TTN | c.63238G>A p.E21080K (on ENST00000591111; = p.E13656K on NM_003319.4) | Missense Mutation (SNP) | VAF 176/305 reads (58%) | PolyPhen probably damaging (0.994); catalogued as rs374492812; ClinVar: uncertain significance / benign / conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- TUSC3 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 29/360 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs749336367, COSV65877700, COSV65883577; called by muse, mutect2
- ZDHHC12 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 28/279 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs751218508; called by muse, mutect2, varscan2
- ZNF444 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 42/534 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.071); catalogued as rs1023916430; called by muse, mutect2
- ZNF729 | c.2982C>A p.C994* | Nonsense Mutation (SNP) | VAF 42/242 reads (17%) | catalogued as rs578220425; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2422G>T p.V808F | Missense Mutation (SNP) | VAF 133/315 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRB1 | c.580G>T p.D194Y | Missense Mutation (SNP) | VAF 66/404 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- AKAP13 | c.2369G>C p.S790T | Missense Mutation (SNP) | VAF 52/274 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- AMER1 | c.2185G>T p.E729* | Nonsense Mutation (SNP) | VAF 409/409 reads (100%) | called by muse, mutect2, varscan2
- AREL1 | c.2156C>G p.A719G | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.796); called by muse, mutect2
- ASMT | c.971C>A p.A324D (on ENST00000381229; = p.A352D on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/674 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CD40LG | c.110T>G p.I37S | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- CDCP1 | c.1139C>A p.S380Y | Missense Mutation (SNP) | VAF 125/282 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- CDK13 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 492/749 reads (66%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- COL6A3 | c.2362C>A p.Q788K | Missense Mutation (SNP) | VAF 135/325 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EFCAB1 | c.271C>A p.H91N | Missense Mutation (SNP) | VAF 31/203 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPHA6 | c.533A>C p.N178T | Missense Mutation (SNP) | VAF 44/308 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ERICH3 | c.4419A>T p.K1473N | Missense Mutation (SNP) | VAF 160/347 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- FOXG1 | c.751A>T p.K251* | Nonsense Mutation (SNP) | VAF 13/336 reads (4%) | called by muse, mutect2
- HLA-DMB | c.347C>A p.S116Y | Missense Mutation (SNP) | VAF 16/372 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- HRH3 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 100/379 reads (26%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.08); called by muse, varscan2
- ICAM4 | c.360A>C p.K120N | Missense Mutation (SNP) | VAF 175/365 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- IGHJ1 | c.28G>A p.G10S | Missense Mutation (SNP) | VAF 205/248 reads (83%) | called by muse, mutect2, varscan2
- KCNA3 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 15/445 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KCNS2 | c.1266A>T p.Q422H | Missense Mutation (SNP) | VAF 40/470 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.601); called by muse, mutect2
- MDC1 | c.113G>A p.S38N | Missense Mutation (SNP) | VAF 40/315 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- MYO16 | c.2423A>G p.E808G | Missense Mutation (SNP) | VAF 226/324 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- OCA2 | c.1704G>T p.E568D | Missense Mutation (SNP) | VAF 67/487 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR6C65 | c.571_572del p.Q191Vfs*30 | Frame Shift Del (DEL) | VAF 42/323 reads (13%) | called by pindel, varscan2
- PCDHGB3 | c.534C>A p.F178L | Missense Mutation (SNP) | VAF 42/357 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PHLDA1 | c.458_460dup p.E153dup | In Frame Ins (INS) | VAF 148/348 reads (43%) | called by pindel, varscan2
- PPFIA1 | c.1144C>A p.L382M | Missense Mutation (SNP) | VAF 87/241 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- PTPRT | c.327C>A p.F109L | Missense Mutation (SNP) | VAF 32/550 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SLC13A1 | c.471G>T p.Q157H | Missense Mutation (SNP) | VAF 26/500 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- SOCS7 | c.1507C>T p.R503* | Nonsense Mutation (SNP) | VAF 1105/3946 reads (28%) | called by muse, mutect2, varscan2
- SPRED3 | c.31C>T p.R11* | Nonsense Mutation (SNP) | VAF 20/392 reads (5%) | called by muse, mutect2
- TET1 | c.29C>G p.S10C | Missense Mutation (SNP) | VAF 79/175 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- TMCC2 | c.958C>G p.L320V | Missense Mutation (SNP) | VAF 28/420 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TTC34 | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 42/632 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- TTN | c.53257G>T p.D17753Y (on ENST00000591111; = p.D10329Y on NM_003319.4) | Missense Mutation (SNP) | VAF 140/283 reads (49%) | PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TTN | c.6866T>A p.I2289N (on ENST00000591111; = p.I2243N on NM_003319.4) | Missense Mutation (SNP) | VAF 52/269 reads (19%) | PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ZNF184 | c.1643A>G p.H548R | Missense Mutation (SNP) | VAF 45/273 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF208 | c.2587T>C p.C863R | Missense Mutation (SNP) | VAF 19/398 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARHGAP35 | c.4179C>T p.S1393= | Silent (SNP) | VAF 153/330 reads (46%) | catalogued as rs201617559; called by muse, mutect2, varscan2
- COL6A5 | c.1851C>T p.C617= | Silent (SNP) | VAF 34/234 reads (15%) | catalogued as rs961502121; called by muse, mutect2, varscan2
- DCLK3 | c.1263C>T p.Y421= | Silent (SNP) | VAF 22/284 reads (8%) | catalogued as rs747084479, COSV69362814; called by muse, mutect2
- DLGAP2 | c.633G>A p.Q211= | Silent (SNP) | VAF 341/724 reads (47%) | called by muse, mutect2, varscan2
- FLI1 | c.996C>T p.Y332= | Silent (SNP) | VAF 83/278 reads (30%) | catalogued as rs752016751, COSV55643083; ClinVar: likely benign; called by muse, mutect2, varscan2
- HEPHL1 | c.1221C>T p.N407= | Silent (SNP) | VAF 75/172 reads (44%) | catalogued as rs557012995, COSV59892696; called by muse, mutect2, varscan2
- HIVEP3 | c.666C>T p.C222= | Silent (SNP) | VAF 177/334 reads (53%) | catalogued as rs756968051, COSV56009945; called by muse, mutect2, varscan2
- KCNH2 | c.546G>A p.S182= | Silent (SNP) | VAF 263/793 reads (33%) | catalogued as rs773030045; called by muse, mutect2, varscan2
- MAGEB6 | c.468G>A p.S156= | Silent (SNP) | VAF 312/313 reads (100%) | catalogued as rs777376582, COSV66871871, COSV66872222; called by muse, mutect2, varscan2
- MEIS1 | c.1074C>T p.F358= | Silent (SNP) | VAF 30/224 reads (13%) | catalogued as rs908617432, COSV55484454; called by muse, mutect2, varscan2
- MUC16 | c.27975C>T p.A9325= | Silent (SNP) | VAF 134/261 reads (51%) | called by muse, mutect2, varscan2
- PLEKHN1 | c.1413C>T p.R471= (on ENST00000379409; = p.R419= on NM_032129.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 162/380 reads (43%) | catalogued as rs937172119; called by muse, mutect2, varscan2
- RFPL2 | c.738C>T p.D246= | Silent (SNP) | VAF 177/400 reads (44%) | catalogued as rs749206718, COSV99964579; called by muse, mutect2, varscan2
- RYK | c.336C>T p.T112= | Silent (SNP) | VAF 92/231 reads (40%) | called by muse, mutect2, varscan2
- S1PR4 | c.51G>A p.A17= | Silent (SNP) | VAF 234/482 reads (49%) | catalogued as rs763097963; called by muse, mutect2, varscan2
- WHRN | c.2499C>T p.G833= | Silent (SNP) | VAF 148/302 reads (49%) | catalogued as rs755304293; called by muse, varscan2
- ZNF786 | c.1893C>T p.R631= | Silent (SNP) | VAF 371/563 reads (66%) | catalogued as COSV60277551; called by muse, mutect2, varscan2
- CELF1 | c.-125T>A | 5'UTR (SNP) | VAF 94/212 reads (44%) | called by muse, mutect2, varscan2
- LAMA4 | c.297+2342G>A | Intron (SNP) | VAF 96/223 reads (43%) | catalogued as rs367709337; called by muse, mutect2, varscan2
- SLITRK2 | chrX:145827914 G>T | 3'Flank (SNP) | VAF 21/360 reads (6%) | called by muse, mutect2
- WDR90 | c.4312-42C>T | Intron (SNP) | VAF 18/554 reads (3%) | called by muse, mutect2
